Gene-level copy-number profile of tumor specimen ALCH-AE79-TTP1-A from ALCHEMIST case ALCH-AE79, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.8 years (18,549 days).
Specimen ALCH-AE79-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01f6f2d6-353c-43c5-a4cd-f74e70e134e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE79-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/aa5733cf-9512-496d-a946-39d893b84725

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 2,825; copy number 2: 55,650; copy number 3: 226; copy number 4: 133; copy number 5: 35; copy number 6: 2; copy number 7: 2; copy number 33: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:12,040,101–12,040,300, 1 gene: AP001542.1.
- chr22:18,527,157–18,530,573, 2 genes: AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 42 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:34,404,663–35,818,007, 25 genes, copy number 5: AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44.
- chr22:18,422,244–18,500,594, 1 gene, copy number 7 (within-gene range 4–7): FAM230A.
- chr22:18,501,794–18,518,161, 2 genes, copy number 5–7: FAM247B, GGTLC3.
- chr22:18,533,646–18,653,617, 8 genes, copy number 5: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,873,543–18,947,741, 6 genes, copy number 5–33: FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
